Somatic mutation profile of tumor specimen C3L-02744-01 (aliquot CPT0188370006) from CPTAC case C3L-02744, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 73.8 years (26,966 days).
Specimen C3L-02744-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f340f0c4-437e-44b0-81c7-40a0b1004c85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02744-31 (Blood Derived Normal), aliquot CPT0183150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8791022-4ce0-4e3c-888f-188ab5ef2899

The open-access MAF lists 87 somatic variants for this specimen: 58 protein-altering or splice-affecting, 20 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 20, Intron 4, Nonsense Mutation 3, In Frame Del 2, Frame Shift Del 2, 3'UTR 2, Splice Site 2, 5'Flank 1, 3'Flank 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 171/382 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 22/26 reads (85%) | catalogued as rs1060500116, CM043772, CM110148, COSV64294267, COSV64296058, COSV64298758; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 203/275 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs483352695, CM942294, COSV52664850, COSV52707693, COSV52949209, COSV53107767; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP5 | c.3735G>C p.K1245N (on ENST00000345122 / NM_001030055.2; = p.K1244N on NM_001173.3) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs746684179; called by muse, mutect2, varscan2
- BRD9 | c.319G>C p.A107P | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.439); catalogued as COSV51321003; called by muse, mutect2, varscan2
- CDC20 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV60522144; called by muse, mutect2, varscan2
- CLCA4 | c.2614C>A p.P872T | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV100991234; called by muse, mutect2, varscan2
- CROCC2 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs901643416, COSV104436350; called by muse, mutect2, varscan2
- CUX1 | c.2596G>T p.E866* | Nonsense Mutation (SNP) | VAF 216/506 reads (43%) | catalogued as COSV52907634; called by muse, mutect2, varscan2
- DHX9 | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 125/516 reads (24%) | catalogued as COSV100841260; called by muse, mutect2, varscan2
- FAM135B | c.2693G>C p.R898T | Missense Mutation (SNP) | VAF 91/362 reads (25%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV52718514; called by muse, mutect2, varscan2
- KIR3DL3 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 659/1166 reads (57%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.88); catalogued as rs564097015; called by muse, mutect2, varscan2
- KIRREL2 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 288/478 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV52876074; called by muse, mutect2, varscan2
- LAMA1 | c.6793G>A p.V2265I | Missense Mutation (SNP) | VAF 206/575 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs766298511; called by muse, mutect2, varscan2
- LGI2 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs372142431; called by muse, varscan2
- MAN1A2 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 98/990 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV62978423; called by muse, mutect2, varscan2
- MAPK1 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 88/233 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs1159689278; called by muse, mutect2, varscan2
- NPFFR1 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 230/265 reads (87%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs1402775549; called by muse, mutect2, varscan2
- PARD6A | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 132/280 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749999364, COSV54669056; called by muse, mutect2, varscan2
- PCDHA7 | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 328/832 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65342151; called by muse, mutect2, varscan2
- PIK3R1 | c.1390G>A p.D464N (on ENST00000521381 / NM_181523.3; = p.D194N on NM_181504.4) | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57131926, COSV57141496, COSV99144900; called by muse, mutect2, varscan2
- POFUT1 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 86/193 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs749782165; called by muse, mutect2, varscan2
- SEC14L3 | c.771+1G>A p.X257_splice | Splice Site (SNP) | VAF 100/315 reads (32%) | catalogued as COSV53179063; called by muse, mutect2, varscan2
- SEMA3F | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 240/274 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs761815872; called by muse, mutect2, varscan2
- SKOR2 | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.81); catalogued as rs1234820508; called by muse, mutect2, varscan2
- TTC6 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.059); catalogued as rs984819301; called by muse, mutect2, varscan2
- ANKRD26 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP2B1 | c.2634+7G>A | Splice Region (SNP) | VAF 100/285 reads (35%) | called by muse, mutect2, varscan2
- BARX1 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 347/521 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CAPN13 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CASP10 | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 199/482 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- CSMD2 | c.8345A>C p.H2782P | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- CTTNBP2NL | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CXCR3 | c.256A>G p.S86G | Missense Mutation (SNP) | VAF 139/306 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- CYRIA | c.296del p.L99Qfs*12 | Frame Shift Del (DEL) | VAF 52/139 reads (37%) | called by mutect2, pindel, varscan2
- DHX9 | c.3619C>T p.R1207W | Missense Mutation (SNP) | VAF 304/995 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- DNAH5 | c.8606_8608del p.T2869_Y2870delinsN | In Frame Del (DEL) | VAF 105/427 reads (25%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.6110G>A p.R2037Q | Missense Mutation (SNP) | VAF 418/1010 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFNB2 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM83H | c.3210G>C p.E1070D | Missense Mutation (SNP) | VAF 82/996 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- FPR2 | c.383T>A p.L128Q | Missense Mutation (SNP) | VAF 13/318 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2
- GFUS | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- IGHG4 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 368/1614 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- JMJD4 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 448/787 reads (57%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- LGI2 | c.857A>T p.D286V | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.12); called by muse, varscan2
- LHFPL1 | c.346A>T p.M116L | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.011); called by muse, varscan2
- MGAM | c.4276A>T p.S1426C | Missense Mutation (SNP) | VAF 191/489 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MORC2 | c.763A>G p.I255V (on ENST00000397641 / NM_001303256.3; = p.I193V on NM_014941.3) | Missense Mutation (SNP) | VAF 125/434 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- NEURL1B | c.988C>G p.P330A | Missense Mutation (SNP) | VAF 77/213 reads (36%) | SIFT tolerated (0.97); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PAN3 | c.76_106del p.A26Sfs*7 | Frame Shift Del (DEL) | VAF 30/64 reads (47%) | called by mutect2, pindel
- PAQR6 | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 141/341 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PPP2CA | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 74/268 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- SEL1L2 | c.387-1G>A p.X129_splice | Splice Site (SNP) | VAF 96/279 reads (34%) | called by muse, mutect2, varscan2
- SLC6A9 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 69/173 reads (40%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNTB2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 164/465 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- SPEN | c.2867_2878del p.G956_K959del | In Frame Del (DEL) | VAF 90/385 reads (23%) | called by mutect2, pindel, varscan2
- THOC5 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ZC3H6 | c.2510T>C p.F837S | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2
- ACSL1 | c.63C>T p.Y21= | Silent (SNP) | VAF 52/151 reads (34%) | catalogued as rs774952873, COSV55663010; called by muse, mutect2, varscan2
- ADAMTS10 | c.2229C>T p.L743= | Silent (SNP) | VAF 242/324 reads (75%) | called by muse, mutect2, varscan2
- C11orf53 | c.372G>A p.A124= | Silent (SNP) | VAF 180/406 reads (44%) | catalogued as rs1278263219; called by muse, mutect2, varscan2
- CTAG2 | c.198C>T p.G66= | Silent (SNP) | VAF 268/678 reads (40%) | catalogued as rs1557241785, COSV55993941; called by muse, mutect2, varscan2
- DDC | c.1419C>T p.D473= | Silent (SNP) | VAF 257/662 reads (39%) | catalogued as rs766373242, COSV100779562, COSV63565165; called by muse, mutect2, varscan2
- EHD1 | c.489G>A p.Q163= | Silent (SNP) | VAF 174/392 reads (44%) | called by muse, mutect2, varscan2
- GPR142 | c.450G>A p.R150= | Silent (SNP) | VAF 112/169 reads (66%) | called by muse, mutect2, varscan2
- KCNH6 | c.1140G>C p.L380= | Silent (SNP) | VAF 16/109 reads (15%) | called by muse, varscan2
- LMTK3 | c.3201C>T p.G1067= | Silent (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- ME1 | c.262A>C p.R88= | Silent (SNP) | VAF 82/255 reads (32%) | called by muse, mutect2, varscan2
- NDNF | c.48C>T p.S16= | Silent (SNP) | VAF 17/213 reads (8%) | catalogued as rs755101871; called by muse, mutect2
- NIT1 | c.954C>G p.L318= | Silent (SNP) | VAF 17/407 reads (4%) | called by muse, mutect2
- NTRK3 | c.1824C>T p.G608= | Silent (SNP) | VAF 192/521 reads (37%) | catalogued as rs376552616; called by muse, mutect2, varscan2
- NWD1 | c.3678C>T p.Y1226= | Silent (SNP) | VAF 85/454 reads (19%) | catalogued as rs747397168, COSV60338903; called by muse, mutect2, varscan2
- PDP1 | c.1011C>G p.V337= | Silent (SNP) | VAF 179/706 reads (25%) | catalogued as COSV52602860; called by muse, mutect2, varscan2
- PIEZO2 | c.5196T>G p.G1732= | Silent (SNP) | VAF 149/390 reads (38%) | called by muse, mutect2, varscan2
- RALGAPA1 | c.2733G>A p.S911= | Silent (SNP) | VAF 76/193 reads (39%) | catalogued as rs758475613; called by muse, mutect2, varscan2
- SEC24C | c.1572T>C p.C524= | Silent (SNP) | VAF 70/100 reads (70%) | called by muse, mutect2, varscan2
- TMEM164 | c.567C>T p.I189= (on ENST00000372068 / NM_032227.4; = p.I40= on NM_017698.2) | Silent (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- ZNF592 | c.1530C>T p.L510= | Silent (SNP) | VAF 332/875 reads (38%) | catalogued as rs146417649; called by muse, mutect2, varscan2
- ABCC6 | c.-51A>T | 5'UTR (SNP) | VAF 5/34 reads (15%) | called by mutect2, varscan2
- AL391839.1 | chr10:32378520 C>G | 3'Flank (SNP) | VAF 7/160 reads (4%) | called by muse, mutect2
- BICDL1 | c.*1078C>T | 3'UTR (SNP) | VAF 82/197 reads (42%) | catalogued as rs1367490867; called by muse, mutect2, varscan2
- COL7A1 | c.7381-30A>T | Intron (SNP) | VAF 133/337 reads (39%) | called by muse, mutect2, varscan2
- DES | c.579-25C>G | Intron (SNP) | VAF 35/1022 reads (3%) | called by muse, mutect2
- FBXO24 | chr7:100584179 G>C | 5'Flank (SNP) | VAF 81/232 reads (35%) | called by muse, mutect2, varscan2
- ILKAP | c.1038+56G>A | Intron (SNP) | VAF 203/551 reads (37%) | catalogued as COSV54520505; called by muse, mutect2, varscan2
- KDM2B | c.2565+14G>A | Intron (SNP) | VAF 155/416 reads (37%) | catalogued as rs782411649; called by muse, mutect2, varscan2
- KLHL4 | c.*2814A>G | 3'UTR (SNP) | VAF 82/211 reads (39%) | called by muse, mutect2, varscan2
